CCDI case PBBTUW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3dfd7ffb-f5a3-4c63-92a1-d80bfa56282e

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain stem; Age at diagnosis: 3.7 years (1,346 days).

Biospecimens (3 samples)
- Sample 0DGRG3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGRHE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DGRHT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
